FM case AD3502 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/99199721-b5d9-45e6-9d72-e47d80041059

Male, 47.2 years: diagnosis not reported by GDC; metastasis biopsied or resected from the testis. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
